Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2Q, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2Q-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-O-3

*Histiocytoma, fibrous
malignant pleomorphic*

8830/3

Site: Leg NOS

49.2

W 3/10/14

Clinical Diagnosis & History:

with new right lower leg mass, biopsy shown to be consistent with sarcoma.

Specimens Submitted:

1: SP: Radical resection of right lower leg

DIAGNOSIS:

1 SOFT TISSUE, RIGHT LOWER LEG; RESECTION: -HIGH GRADE PLEOMORPHIC SARCOMA CONSISTENT WITH MALIGNANT FIBROUS HISTIOCYTOMA.

- TUMOR ULCERATES INTO SKIN AND EXTENDS FOCALLY INTO SKELETAL MUSCLE.

-TUMOR SIZE: 9 X 8 X 4 CM

-TUMOR IS PREDOMINANTLY VIABLE WITH FOCAL NECROSIS (ABOUT 5%).

-MARGINS OF RESECTION ARE FREE OF TUMOR. DEEP MARGIN IS 0.3 CM FROM TUMOR AND IS LIMITED BY SKELETAL MUSCLE. ALL OTHER MARGINS ARE WIDELY NEGATIVE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and labeled " radical resection of right lower leg" and consists of an oriented 15 x 14 cm round portion of skin excised to a depth of 2.5 cm with a fungating 9 x 8 x 4 cm tumor extending above the surrounding skin surface. The tumor has ulcerated the skin with a thin fibrous capsule on the surface overlying visible tumor. There is hemorrhagic crust also on the surface. The tumor has been oriented with a short suture marking superior and a long suture marking "lateral". The suture marking "lateral" appears to be on the deep resection surface and is sutured to skeletal muscle. Therefore, this margin will be considered deep.

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2 -----
The specimen will be oriented based on the superior suture as viewed from anterior. The specimen is inked as follows: superior red, inferior green, lateral blue, medial orange, deep black. The closest margin is the deep (clearance 0.5 cm). All of the skin margins are greater than 1 cm away from the tumor. The cut surface of the tumor is fleshy, pale tan-white with scattered areas of hemorrhage. The tumor appears predominantly viable. Gross photographs are taken. TPS is given. Representatively submitted.

S-superior margin
I-inferior margin
L-lateral margin
M-medial margin
D-deep margin
TS-tumor with overlying surface (skin or crust)
T-tumor

Summary of Sections:

Part 1: SP: Radical resection of right lower leg

Block	Sect.	Site	PCs
1		D	1
1		I	1
1		L	1
1		M	1
1		S	1
8		T	8
3		TS	3

** End of Report **

hw 11/20/14

Source: NCI Genomic Data Commons file bfc3fcb1-577a-4daf-9907-e85455df688a (TCGA-DX-AB2Q.FC919CE2-2F19-46D0-BDF8-EBA6A89DAD71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).